Somatic mutation profile of tumor specimen C3L-00927-02 (aliquot CPT0063480009) from CPTAC case C3L-00927, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 74.4 years (27,187 days).
Specimen C3L-00927-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef49d01e-8b64-4405-8a6b-097d756962dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00927-31 (Blood Derived Normal), aliquot CPT0065270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a6c16ff-0714-48f2-952f-c147deccb584

The open-access MAF lists 248 somatic variants for this specimen: 184 protein-altering or splice-affecting, 42 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 42, Nonsense Mutation 8, Intron 8, Frame Shift Del 7, RNA 5, 5'UTR 4, 3'UTR 4, Splice Site 3, Splice Region 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN7 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760956030, CM034393, COSV104387173; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 129/304 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB4 | c.1057T>C p.C353R | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as rs1393932488, COSV55941252; called by muse, mutect2, varscan2
- ACSM2A | c.1177C>A p.Q393K (on ENST00000219054; = p.Q314K on NM_001308169.2) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as COSV99524976; called by muse, mutect2, varscan2
- ADGRB3 | c.2322G>C p.L774F | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65393281, COSV65393816; called by muse, mutect2, varscan2
- ADGRV1 | c.15414del p.E5139Rfs*6 | Frame Shift Del (DEL) | VAF 72/172 reads (42%) | catalogued as rs1286940284, COSV67994089; called by mutect2, pindel*, varscan2
- C2orf16 | c.5050A>G p.R1684G | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); catalogued as rs1285244691; called by muse, mutect2, varscan2
- C7 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV57475725; called by muse, mutect2, varscan2
- CALCB | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 102/421 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs376051795; called by muse, mutect2, varscan2
- CCDC141 | c.2933A>G p.D978G | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs138429319; called by muse, mutect2, varscan2
- CCDC168 | c.17393C>T p.S5798F | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV59420822; called by muse, mutect2, varscan2
- CFHR5 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs868847668, COSV56820969; called by muse, mutect2, varscan2
- CILP2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs769932373, COSV52280776; called by muse, mutect2
- CMTM2 | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs760310900; called by muse, mutect2, varscan2
- COL11A1 | c.1033G>C p.G345R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV62175198, COSV62189181; called by muse, mutect2, varscan2
- CRYBG3 | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs1314353474; called by muse, mutect2, varscan2
- CSNK2A3 | c.131A>T p.K44I | Missense Mutation (SNP) | VAF 72/779 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1396091839; called by muse, mutect2
- CYP11B1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 106/1664 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1398082976; called by muse, mutect2
- DCAF4L2 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV60480617; called by muse, mutect2, varscan2
- EFCAB5 | c.2078T>C p.I693T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs750996565; called by muse, mutect2, varscan2
- FAM234A | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV51453284, COSV99395824; called by muse, mutect2, varscan2
- FAT3 | c.2225G>T p.G742V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188907686, COSV99970168; called by muse, mutect2, varscan2
- FBN1 | c.4462G>T p.V1488L | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1566904712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FXR1 | c.1145C>G p.S382C | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV59764017; called by muse, varscan2
- GRM6 | c.2333C>A p.T778N | Missense Mutation (SNP) | VAF 78/144 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1379700638; called by muse, mutect2, varscan2
- HIPK3 | c.3499G>A p.G1167S | Missense Mutation (SNP) | VAF 83/309 reads (27%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.545); catalogued as rs1173539375; called by muse, mutect2, varscan2
- HS3ST2 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs1330878936; called by muse, mutect2, varscan2
- JAKMIP2 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV54597549; called by muse, mutect2, varscan2
- KCNC2 | c.1343G>C p.W448S | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV54361296; called by muse, mutect2, varscan2
- KIAA1671 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1300342042; called by muse, mutect2, varscan2
- KIRREL3 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs369207399; called by muse, mutect2, varscan2
- LCT | c.3524G>C p.R1175T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51551967; called by muse, mutect2, varscan2
- LRP1B | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs545142973, COSV67184445, COSV67241706; called by muse, mutect2
- LZTS3 | c.1642G>T p.G548W (on ENST00000329152; = p.G502W on NM_001282533.2) | Missense Mutation (SNP) | VAF 185/267 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs759625241; called by muse, mutect2, varscan2
- MAP1B | c.1912G>T p.V638L | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1230550659; called by muse, mutect2, varscan2
- NOTCH1 | c.1904-1G>T p.X635_splice | Splice Site (SNP) | VAF 456/679 reads (67%) | catalogued as COSV53087809; called by muse, mutect2, varscan2
- OPRL1 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 174/267 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV61092600; called by muse, mutect2, varscan2
- OR10G7 | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100389941, COSV57866127; called by muse, mutect2, varscan2
- OR2M3 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs202069600; called by muse, mutect2, varscan2
- OR2T34 | c.614A>T p.Y205F | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV60899780, COSV60900889; called by muse, mutect2, varscan2
- OR4K15 | c.437G>T p.R146L (on ENST00000305051; = p.R122L on NM_001005486.1) | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100521044, COSV59303142; called by muse, mutect2, varscan2
- OR6P1 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs554137403, COSV58109046; called by muse, mutect2, varscan2
- OR8B12 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs1402803748, COSV60912800; called by muse, mutect2, varscan2
- OXER1 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54309890; called by muse, mutect2, varscan2
- PAIP1 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 75/108 reads (69%) | catalogued as rs1287709801; called by muse, mutect2, varscan2
- PCDHB1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 89/188 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as rs1554267041; called by muse, mutect2, varscan2
- PCDHB7 | c.2159T>A p.V720E | Missense Mutation (SNP) | VAF 119/211 reads (56%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs1381527111; called by muse, mutect2, varscan2
- PCLO | c.14187C>A p.D4729E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1300081996; called by muse, mutect2, varscan2
- PDGFRA | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.869); catalogued as COSV57272316; called by muse, mutect2, varscan2
- PDZRN4 | c.1932C>A p.D644E (on ENST00000402685 / NM_001164595.2; = p.D386E on NM_013377.4) | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.867); catalogued as COSV54208191; called by muse, mutect2, varscan2
- PPP1R2B | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV101338087; called by muse, mutect2, varscan2
- PRC1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs750554170, COSV62696045; called by muse, mutect2, varscan2
- PTGS1 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 155/230 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99793612; called by muse, mutect2, varscan2
- RNPC3 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV71076891; called by muse, mutect2, varscan2
- RUNX1T1 | c.1490C>T p.A497V (on ENST00000265814 / NM_001198628.1; = p.A470V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs763527961, COSV56143789, COSV99752876; called by mutect2, varscan2
- SFXN4 | c.336G>A p.A112= | Splice Region (SNP) | VAF 45/175 reads (26%) | catalogued as rs770952989; called by muse, mutect2, varscan2
- SLC44A5 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1376567219, COSV99056965; called by muse, mutect2, varscan2
- SLC6A18 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.912); catalogued as rs952231318, COSV57249994; called by muse, mutect2, varscan2
- SLCO1B3 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs200539697; called by muse, mutect2, varscan2
- SPACA1 | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99389647; called by muse, mutect2, varscan2
- SSTR1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV57456388; called by muse, mutect2, varscan2
- TDRD5 | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54247324; called by muse, mutect2, varscan2
- TM6SF2 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.643); catalogued as rs758849576; called by muse, mutect2, varscan2
- TMEM181 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV100892577; called by muse, mutect2, varscan2
- TRPC3 | c.320C>A p.T107N (on ENST00000379645 / NM_001366479.2; = p.T34N on NM_003305.2) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV53372870; called by muse, mutect2, varscan2
- TYR | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM100983; called by muse, varscan2
- USP49 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs548556992, COSV51897822; called by muse, mutect2, varscan2
- VPS13B | c.3880A>G p.I1294V | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760928396; called by muse, mutect2, varscan2
- WDR93 | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 23/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1184593779; called by muse, mutect2
- ZBTB34 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 184/252 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV59859669, COSV59860232; called by muse, mutect2, varscan2
- ZBTB34 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100043598; called by mutect2, varscan2
- ZSCAN23 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs1308777004; called by muse, mutect2, varscan2
- AASDH | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 71/134 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC8 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ACTR3 | c.925A>C p.I309L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGBL1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 44/468 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- AGO1 | c.1955A>G p.Y652C | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ALPK1 | c.2310T>A p.S770R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AMBRA1 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AMIGO3 | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 101/199 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ANKRD45 | c.761G>T p.S254I | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ATAD2B | c.3155C>T p.A1052V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ATRNL1 | c.3982C>T p.R1328* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- BEND3 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 74/1912 reads (4%) | called by muse, mutect2
- BEND3 | c.2085C>G p.S695R | Missense Mutation (SNP) | VAF 32/1208 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.421); called by muse, mutect2
- BPTF | c.1432A>G p.I478V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- C6orf118 | c.1108A>G p.K370E | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- CACNA1E | c.1271C>T p.T424I | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CATSPER2 | c.499dup p.S167Ffs*15 | Frame Shift Ins (INS) | VAF 38/152 reads (25%) | called by mutect2, varscan2
- CCDC178 | c.1847A>G p.D616G | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCL4 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 146/421 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CCNL2 | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CFAP54 | c.1384C>T p.L462F | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.74); PolyPhen benign (0.009); called by muse, varscan2
- CHST5 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 127/375 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CMTR2 | c.1479A>T p.L493F | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTN6 | c.2605C>A p.L869M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL11A1 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CUL9 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- DAGLA | c.2464T>C p.Y822H | Missense Mutation (SNP) | VAF 118/328 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- DCAF12L2 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 142/231 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DNAH10 | c.3776C>T p.A1259V (on ENST00000409039; = p.A1198V on NM_207437.3) | Missense Mutation (SNP) | VAF 74/112 reads (66%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DSC2 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DTNA | c.1001+2T>A p.X334_splice | Splice Site (SNP) | VAF 51/212 reads (24%) | called by muse, mutect2, varscan2
- DYRK3 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDAR | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM131C | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- FAM13C | c.521_522delinsT p.Q174Lfs*79 | Frame Shift Del (DEL) | VAF 38/225 reads (17%) | called by pindel, varscan2*
- FPR2 | c.557C>G p.T186S | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- FTO | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 105/288 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- GABRG2 | c.1355del p.K452Rfs*83 (on ENST00000361925 / NM_001375343.1; = p.K412Rfs*83 on NM_000816.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 65/161 reads (40%) | called by mutect2, pindel, varscan2
- GRID1 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRID1 | c.841del p.V281Sfs*48 | Frame Shift Del (DEL) | VAF 56/188 reads (30%) | called by mutect2, pindel, varscan2
- GRIP1 | c.2247G>C p.L749F (on ENST00000359742 / NM_001379345.1; = p.L697F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/163 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GSDMD | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 131/1422 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- IGDCC4 | c.836G>C p.R279P | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQCK | c.731A>T p.Q244L | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IQUB | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ISG20 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 721/955 reads (75%) | called by muse, mutect2, varscan2
- JHY | c.1109G>T p.C370F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- JMJD1C | c.3871G>T p.V1291L | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KALRN | c.1030T>G p.Y344D | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL4 | c.178A>G p.N60D | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LATS2 | c.1855C>G p.Q619E | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.057); called by muse, varscan2
- LRFN2 | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 96/182 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LYL1 | c.557T>A p.L186Q | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- LYST | c.7832G>C p.R2611P | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAP3K15 | c.2715G>C p.E905D | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MECOM | c.2282A>T p.Y761F (on ENST00000468789 / NM_001105078.4; = p.Y949F on NM_004991.4) | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- MLYCD | c.1305G>A p.W435* | Nonsense Mutation (SNP) | VAF 64/182 reads (35%) | called by muse, mutect2, varscan2
- MMP27 | c.968C>G p.P323R | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MYO18B | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 139/242 reads (57%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NLRP13 | c.810C>A p.C270* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- NTS | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- NXPE2 | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ONECUT3 | c.1258G>C p.V420L | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- OR2W3 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR5AP2 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR5D16 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- OR6M1 | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDCD11 | c.4508A>T p.Y1503F | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PEG3 | c.4714C>G p.L1572V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PKHD1L1 | c.10939A>G p.K3647E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLEKHA4 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 117/434 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PLPPR3 | c.1549_1550del p.A517Qfs*? (on ENST00000520876 / NM_001270366.2; = p.A545Qfs*? on NM_024888.2) | Frame Shift Del (DEL) | VAF 38/119 reads (32%) | called by pindel, varscan2
- POTEH | c.1392G>C p.M464I | Missense Mutation (SNP) | VAF 48/572 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- PRKCA | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRR23C | c.283C>A p.H95N | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PTX3 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- PUS7L | c.1417A>G p.R473G | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RBM26 | c.416G>T p.R139I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- RGS7 | c.419A>T p.K140M | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RHCE | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 93/431 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RORC | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPGRIP1L | c.3547G>T p.A1183S | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- RUNX1T1 | c.997C>A p.H333N (on ENST00000265814 / NM_001198628.1; = p.H306N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGIP1 | c.2383G>T p.G795* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- SGK1 | c.820del p.Y274Mfs*37 | Frame Shift Del (DEL) | VAF 30/112 reads (27%) | called by mutect2, pindel, varscan2
- SHANK1 | c.5690G>T p.G1897V | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SHANK1 | c.5107G>A p.E1703K | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- SLC12A3 | c.1591A>T p.I531F | Missense Mutation (SNP) | VAF 139/415 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLC3A1 | c.1269C>G p.S423R | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SMYD4 | c.858C>G p.D286E | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SNED1 | c.2708C>A p.A903D | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SORCS1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- SP5 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 145/479 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- TAF2 | c.1405A>G p.M469V | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- TAF6 | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 107/189 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- TAOK2 | c.1901G>T p.R634L | Missense Mutation (SNP) | VAF 131/391 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- THSD7A | c.3705T>G p.S1235R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TLN1 | c.3169G>T p.V1057L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM13 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- TRIM64C | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 102/300 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRPA1 | c.2923A>G p.R975G | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPC6 | c.1131T>C p.F377= | Splice Region (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.6776A>T p.K2259I (on ENST00000591111; = p.K2213I on NM_003319.4) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- UNC13C | c.5146A>C p.K1716Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP34 | c.6223G>C p.A2075P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- VPS13C | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZDHHC17 | c.544-1G>T p.X182_splice | Splice Site (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- ZIM3 | c.651C>A p.H217Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF350 | c.803del p.G268Afs*67 | Frame Shift Del (DEL) | VAF 43/130 reads (33%) | called by mutect2, pindel, varscan2
- ZNF496 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ZNF790 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | called by mutect2, varscan2
- ZNF98 | c.1452T>A p.H484Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC39 | c.1501T>C p.L501= | Silent (SNP) | VAF 32/158 reads (20%) | called by muse, varscan2
- CDC27 | c.1512A>G p.Q504= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV50575845; called by muse, mutect2, varscan2
- CLMN | c.636G>T p.A212= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV54183194; called by muse, mutect2, varscan2
- CYP11A1 | c.273G>A p.E91= | Silent (SNP) | VAF 59/170 reads (35%) | catalogued as rs747254010; called by muse, mutect2, varscan2
- CYP11B1 | c.900G>A p.S300= | Silent (SNP) | VAF 110/1680 reads (7%) | catalogued as rs778864300, COSV52828972; called by muse, mutect2
- DDAH1 | c.627C>T p.Y209= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs776328065; called by muse, mutect2, varscan2
- FADS3 | c.858G>A p.A286= | Silent (SNP) | VAF 22/276 reads (8%) | catalogued as rs369043120; called by muse, mutect2
- GBA2 | c.1668C>T p.L556= | Silent (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- GDPD5 | c.252C>T p.S84= | Silent (SNP) | VAF 68/210 reads (32%) | catalogued as rs200975282; called by muse, mutect2, varscan2
- GNA12 | c.489C>T p.I163= | Silent (SNP) | VAF 114/344 reads (33%) | called by muse, mutect2, varscan2
- GNB1 | c.537G>A p.T179= | Silent (SNP) | VAF 61/297 reads (21%) | catalogued as rs1332565193, COSV66100663; called by muse, mutect2, varscan2
- GOLGA6C | c.111C>T p.S37= | Silent (SNP) | VAF 47/223 reads (21%) | catalogued as COSV56036520; called by muse, mutect2, varscan2
- H1-8 | c.45T>A p.T15= | Silent (SNP) | VAF 55/260 reads (21%) | called by muse, mutect2, varscan2
- IGKV1-27 | c.27C>A p.L9= | Silent (SNP) | VAF 34/139 reads (24%) | called by muse, mutect2, varscan2
- JPH2 | c.633C>T p.A211= | Silent (SNP) | VAF 78/287 reads (27%) | catalogued as rs1372602717; called by muse, mutect2, varscan2
- KCNH8 | c.3318T>C p.N1106= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs757241684, COSV100111132; called by muse, varscan2
- KIF24 | c.1053G>A p.K351= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs373687214; called by muse, mutect2, varscan2
- KLHL31 | c.165T>C p.Y55= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs749858883; called by muse, mutect2, varscan2
- LRFN2 | c.2043G>T p.G681= | Silent (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- LRRC24 | c.1491G>C p.A497= | Silent (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.1204C>A p.R402= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV63041638; called by muse, mutect2, varscan2
- LVRN | c.2502A>T p.G834= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- MCF2 | c.150G>A p.L50= (on ENST00000520602; = p.L7= on NM_001099855.1) | Silent (SNP) | VAF 22/30 reads (73%) | called by muse, mutect2, varscan2
- NDN | c.237C>A p.A79= | Silent (SNP) | VAF 41/120 reads (34%) | called by muse, mutect2, varscan2
- NOTCH1 | c.4077C>T p.N1359= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as rs775108554; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR10R2 | c.921C>A p.P307= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1308801738, COSV63769476; called by muse, mutect2, varscan2
- PCDH15 | c.1446A>T p.T482= | Silent (SNP) | VAF 44/149 reads (30%) | called by muse, mutect2, varscan2
- PPARGC1A | c.786G>T p.L262= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- PTPRQ | c.2121G>T p.P707= (on ENST00000616559; = p.P665= on NM_001145026.2) | Silent (SNP) | VAF 52/87 reads (60%) | called by muse, mutect2, varscan2
- RAB44 | c.361A>C p.R121= | Silent (SNP) | VAF 65/230 reads (28%) | called by muse, mutect2, varscan2
- RYR1 | c.1107C>A p.G369= | Silent (SNP) | VAF 75/264 reads (28%) | catalogued as COSV62105552; called by muse, mutect2, varscan2
- SMCR8 | c.1425G>A p.L475= | Silent (SNP) | VAF 46/95 reads (48%) | called by muse, mutect2, varscan2
- SPTBN4 | c.6751C>A p.R2251= | Silent (SNP) | VAF 72/245 reads (29%) | called by muse, mutect2, varscan2
- STK31 | c.2211G>A p.K737= | Silent (SNP) | VAF 33/116 reads (28%) | called by muse, mutect2, varscan2
- TUFM | c.6C>G p.T2= | Silent (SNP) | VAF 48/150 reads (32%) | called by muse, mutect2, varscan2
- TYR | c.369C>A p.I123= | Silent (SNP) | VAF 66/203 reads (33%) | called by muse, varscan2
- USH2A | c.8955C>A p.G2985= | Silent (SNP) | VAF 60/226 reads (27%) | called by mutect2, varscan2
- VOPP1 | c.321C>T p.P107= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs370249367, COSV99566946; called by muse, mutect2, varscan2
- ZDHHC15 | c.921G>C p.L307= | Silent (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- ZIC1 | c.615C>A p.A205= | Silent (SNP) | VAF 83/300 reads (28%) | catalogued as COSV99292085; called by muse, mutect2, varscan2
- ZNF460 | c.63A>G p.T21= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs1463028424; called by muse, mutect2, varscan2
- ZNF658 | c.2298G>T p.G766= | Silent (SNP) | VAF 42/59 reads (71%) | called by mutect2, varscan2
- AC133561.1 | n.1959del | RNA (DEL) | VAF 62/228 reads (27%) | called by mutect2, varscan2
- ACKR1 | c.-37del | 5'UTR (DEL) | VAF 59/225 reads (26%) | called by mutect2, pindel, varscan2
- ARPP21 | c.2032+565C>A | Intron (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- CCDC162P | n.5752G>T | RNA (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- CLK2 | c.1226+10del | Intron (DEL) | VAF 28/119 reads (24%) | called by mutect2, pindel, varscan2
- COL4A2 | c.1340-588C>T | Intron (SNP) | VAF 70/216 reads (32%) | called by muse, mutect2, varscan2
- CRLF2 | c.-2G>A | 5'UTR (SNP) | VAF 65/135 reads (48%) | called by muse, mutect2, varscan2
- EPB41L2 | c.2044-246C>T | Intron (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- FAS | c.*1114del | 3'UTR (DEL) | VAF 80/234 reads (34%) | called by pindel, varscan2
- GSDMD | c.410+69A>C | Intron (SNP) | VAF 42/582 reads (7%) | called by muse, mutect2
- LINC00922 | n.857G>A | RNA (SNP) | VAF 33/115 reads (29%) | catalogued as rs1416202937; called by muse, mutect2, varscan2
- LYPLA2 | c.-9G>A | 5'UTR (SNP) | VAF 92/188 reads (49%) | called by muse, mutect2, varscan2
- MAN1A2 | c.*2194G>C | 3'UTR (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- MIR4771-1 | chr2:87193571 C>G | 5'Flank (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2, varscan2
- MRRFP1 | n.143G>T | RNA (SNP) | VAF 36/63 reads (57%) | catalogued as rs1398721950; called by muse, mutect2, varscan2
- OSGIN1 | n.819G>T | RNA (SNP) | VAF 52/143 reads (36%) | called by muse, mutect2, varscan2
- PEG10 | c.*1118G>T | 3'UTR (SNP) | VAF 33/146 reads (23%) | catalogued as COSV71788196; called by muse, mutect2, varscan2
- PPP3CB | c.1366+80A>G | Intron (SNP) | VAF 44/152 reads (29%) | called by muse, mutect2, varscan2
- PSMA1 | c.-20G>T | 5'UTR (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- RNF166 | c.*903C>T | 3'UTR (SNP) | VAF 62/201 reads (31%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.1334+50C>T | Intron (SNP) | VAF 76/288 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.10360+1469C>G | Intron (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
